MMRF case MMRF_2279 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fba1eb1f-7e57-46fc-a7d5-7f4cceadbc27

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,813 days); ISS stage: I; Days to last known disease status: 847 days (2.3 years); Days to last follow up: 847 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 847.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 2): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Beta 2 Microglobulin 3.41 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.2 mmol/L; Calcium 2.67 mmol/L; Albumin 48 g/L; Total Protein 9.5 g/dL; Glucose 6.5 mmol/L.
- Day 86 (ECOG 3): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 47 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.27 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 6.4 mmol/L.
- Day 180: Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.31 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 5.2 mmol/L.
- Day 259: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.34 mg/dL; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 52 µmol/L; Blood Urea Nitrogen 4.4 mmol/L; Calcium 2.27 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 9.1 mmol/L.
- Day 373: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 59 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL.
- Day 457: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 63 µmol/L; Blood Urea Nitrogen 3.6 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 5.7 mmol/L.
- Day 553: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 74 µmol/L; Blood Urea Nitrogen 4.8 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 6.3 mmol/L.
- Day 637: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.7 mmol/L; Calcium 2.26 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.1 mmol/L.
- Day 721: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 4.8 mmol/L; Calcium 2.26 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.9 mmol/L.

Other clinical attributes
- Day -5: Weight: 76 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2279_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2279_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
